Somatic mutation profile of tumor specimen TCGA-D7-A4Z0-01A (aliquot TCGA-D7-A4Z0-01A-22D-A25D-08) from TCGA case TCGA-D7-A4Z0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.6 years (22,129 days).
Specimen TCGA-D7-A4Z0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d9a2d9d-b0be-46b8-a3cd-71f0904f85a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4Z0-10A (Blood Derived Normal), aliquot TCGA-D7-A4Z0-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff8dd09-8da9-47c0-a10b-1b63182906a8

The open-access MAF lists 325 somatic variants for this specimen: 260 protein-altering or splice-affecting, 54 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 54, Nonsense Mutation 6, Intron 5, Frame Shift Del 3, RNA 3, 3'UTR 2, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2, varscan2
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 20/164 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2, varscan2
- ERBB4 | c.3668A>T p.K1223M | Missense Mutation (SNP) | VAF 24/212 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV61475135, COSV61522424, COSV61527805; called by muse, mutect2, varscan2
- ERBB4 | c.2320A>G p.S774G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.35); PolyPhen possibly damaging (0.727); catalogued as COSV61512853, COSV61527820; called by muse, mutect2, varscan2
- ABCB5 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV51702528, COSV51719981; called by muse, mutect2, varscan2
- ADAMTS1 | c.2336T>G p.L779R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99536166; called by muse, mutect2, varscan2
- ADAMTS1 | c.2098G>A p.G700S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53173899; called by muse, mutect2, varscan2
- ADAMTS1 | c.2008T>G p.F670V | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV53173913; called by muse, mutect2, varscan2
- ADGRG4 | c.2063A>G p.E688G | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54968744; called by muse, mutect2, varscan2
- ADGRL4 | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100875975; called by muse, mutect2, varscan2
- ADGRL4 | c.1179C>A p.Y393* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100875978; called by muse, mutect2, varscan2
- AFF2 | c.774A>T p.L258F | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60683826; called by muse, mutect2, varscan2
- AGBL1 | c.2692T>C p.C898R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66861853; called by muse, mutect2, varscan2
- AGGF1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs747964895, COSV57228264; called by muse, mutect2, varscan2
- AKAP6 | c.6917T>G p.L2306R | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs529053250, COSV55213755; called by muse, mutect2, varscan2
- AMER1 | c.1358T>C p.L453P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57656352, COSV57670180; called by muse, mutect2, varscan2
- ARMC4 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1564573831, COSV53468946, COSV99518489; called by muse, mutect2
- ATP10A | c.2200T>G p.F734V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV63525890; called by muse, mutect2, varscan2
- ATP11C | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV59575806; called by muse, mutect2, varscan2
- ATP8A2 | c.3125T>C p.F1042S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54978807; called by muse, mutect2, varscan2
- BBS9 | c.1679T>G p.L560R (on ENST00000242067 / NM_001348036.1; = p.L520R on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.242); catalogued as COSV54177737, COSV54190067; called by muse, mutect2, varscan2
- BMP3 | c.938A>C p.E313A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV51096637; called by muse, mutect2, varscan2
- BRD1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779060123, COSV53462247; called by muse, mutect2, varscan2
- CACHD1 | c.3676G>A p.D1226N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV51556210, COSV51560807; called by muse, mutect2, varscan2
- CCDC63 | c.1525T>G p.F509V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as COSV57531616; called by muse, mutect2, varscan2
- CCNB3 | c.3832A>G p.T1278A | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52080615; called by muse, mutect2
- CD1D | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs780562127, COSV63810210; called by muse, mutect2, varscan2
- CD207 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69652860; called by muse, varscan2
- CD209 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99214012; called by muse, mutect2, varscan2
- CDH2 | c.2099T>G p.V700G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52298305; called by muse, mutect2, varscan2
- CEACAM8 | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.942); catalogued as COSV54991025, COSV54992037; called by muse, mutect2, varscan2
- CFAP54 | c.6248T>G p.V2083G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61575765; called by muse, mutect2
- CHM | c.981A>C p.Q327H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV63305170; called by muse, mutect2, varscan2
- CNTN3 | c.1849T>C p.S617P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55162297; called by muse, mutect2, varscan2
- CNTNAP5 | c.2651A>T p.K884M | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70515252; called by muse, mutect2, varscan2
- COL11A1 | c.2510T>A p.L837H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100614690, COSV62175663, COSV62200150; called by muse, mutect2
- COL19A1 | c.1165T>G p.L389V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as COSV59590465; called by muse, mutect2, varscan2
- COL4A4 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61631544, COSV61637248; called by muse, mutect2, varscan2
- COQ3 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54642394; called by muse, mutect2, varscan2
- CPXM2 | c.2195A>C p.K732T | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53872059; called by muse, mutect2, varscan2
- CSMD1 | c.1787T>G p.I596S (on ENST00000520002; = p.I595S on NM_033225.6) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59381693, COSV59393099; called by muse, mutect2
- CSMD3 | c.8677T>C p.F2893L (on ENST00000297405 / NM_001363185.1; = p.F2724L on NM_052900.3) | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52338035; called by muse, mutect2
- CSMD3 | c.6940A>G p.R2314G (on ENST00000297405 / NM_001363185.1; = p.R2210G on NM_052900.3) | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs750004286, COSV52160571, COSV99846677; called by muse, mutect2, varscan2
- CSMD3 | c.1593A>T p.E531D (on ENST00000297405 / NM_001363185.1; = p.E427D on NM_052900.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV52105113, COSV52338075; called by muse, mutect2
- CTNND1 | c.2458C>T p.R820* (on ENST00000399050 / NM_001085458.2; = p.R814* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV62382612; called by muse, mutect2, varscan2
- CYP2D6 | c.1390T>G p.F464V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62245793; called by muse, mutect2, varscan2
- CYP4F12 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs150856722, COSV61172750; called by muse, mutect2, varscan2
- DCAF4L2 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV60483196; called by muse, mutect2, varscan2
- DCDC2 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV65831068, COSV65834157; called by muse, mutect2
- DDI1 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV56395885; called by mutect2, varscan2
- DNAH3 | c.6941G>A p.R2314H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771648891, COSV54556823; called by muse, mutect2, varscan2
- DNAH5 | c.11846T>G p.L3949R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334354600, COSV54201621, COSV54257873; called by muse, mutect2, varscan2
- DNAH5 | c.9767A>C p.K3256T | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54218741; called by muse, mutect2, varscan2
- DNAH7 | c.4259T>G p.L1420R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56789778; called by muse, mutect2, varscan2
- DNAH9 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs781679184, COSV52380087; called by muse, mutect2, varscan2
- DNAH9 | c.7229A>C p.K2410T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52353935, COSV52380102; called by muse, mutect2, varscan2
- DOCK10 | c.2804A>T p.K935M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV51362317; called by muse, mutect2, varscan2
- DPYS | c.1171A>G p.R391G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, varscan2
- DRC1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs372509418; called by muse, mutect2, varscan2
- DSPP | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.04); catalogued as COSV56817344; called by muse, mutect2, varscan2
- DYNC2I1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV68107560; called by muse, mutect2, varscan2
- EDNRB | c.934A>C p.I312L (on ENST00000377211 / NM_001201397.1; = p.I222L on NM_000115.5) | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV57528687; called by muse, mutect2, varscan2
- EDNRB | c.308T>G p.V103G (on ENST00000377211 / NM_001201397.1; = p.V13G on NM_000115.5) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV100527321, COSV57528708; called by muse, mutect2, varscan2
- EPHA6 | c.2721A>C p.K907N (on ENST00000389672 / NM_001080448.3; = p.K299N on NM_173655.4) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761211944, COSV101063569, COSV67588567; called by muse, mutect2, varscan2
- EPHA6 | c.3089A>C p.N1030T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67596127; called by muse, mutect2, varscan2
- EXOC6B | c.2101T>G p.L701V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55556690; called by muse, mutect2
- F13A1 | c.2082A>C p.E694D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV53555871; called by muse, mutect2, varscan2
- FAM114A2 | c.986T>G p.L329R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV61078900; called by muse, mutect2, varscan2
- FAM71B | c.924A>C p.Q308H | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV57231711; called by muse, mutect2, varscan2
- FAM71C | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV100175836, COSV60944620; called by muse, mutect2, varscan2
- FAM9A | c.804A>C p.E268D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.388); catalogued as COSV66813822; called by muse, mutect2, varscan2
- FAT4 | c.8657T>G p.L2886R | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58674921, COSV58711887; called by muse, mutect2, varscan2
- FATE1 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64849395; called by muse, mutect2, varscan2
- FGF13 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59550908; called by muse, mutect2, varscan2
- FLT1 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs137937570; called by muse, mutect2
- FMN2 | c.2321A>G p.E774G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as COSV60457438; called by muse, mutect2
- FMN2 | c.4883A>G p.E1628G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV60457446; called by muse, mutect2, varscan2
- FMR1 | c.586T>G p.L196V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.443); catalogued as COSV54427939; called by muse, mutect2, varscan2
- FSHR | c.902T>G p.V301G | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58636539; called by muse, mutect2, varscan2
- GABRA3 | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100942738, COSV64806209; called by muse, varscan2
- GALNT17 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV61195349; called by muse, mutect2
- GLI3 | c.2479C>A p.L827I | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV67895601; called by muse, mutect2, varscan2
- GLP2R | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52330128; called by muse, mutect2, varscan2
- GNL3L | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV60577823; called by muse, mutect2, varscan2
- GPC6 | c.308A>T p.K103M | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV65517892, COSV65540776; called by muse, mutect2, varscan2
- GPC6 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65540779; called by muse, mutect2, varscan2
- GRIA4 | c.2529A>C p.E843D | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV56879830, COSV99231698; called by muse, mutect2, varscan2
- GRIN3A | c.1531A>C p.S511R | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV62451002, COSV62459081; called by muse, mutect2, varscan2
- GRM7 | c.1067A>C p.E356A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV63174910; called by muse, mutect2, varscan2
- GRM7 | c.2561T>C p.L854P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV63174930; called by muse, mutect2, varscan2
- GSG1 | c.694T>G p.L232V (on ENST00000651961 / NM_001080555.4; = p.L237R on NM_031289.5) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV52198123; called by muse, mutect2, varscan2
- GUCY1A1 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs142097871, COSV56657142; called by muse, mutect2, varscan2
- HAS2 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58267770; called by muse, mutect2, varscan2
- HBD | c.54A>C p.K18N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53082979; called by muse, mutect2, varscan2
- HMCN1 | c.7307T>G p.L2436R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54895385, COSV54946465; called by muse, mutect2, varscan2
- HMCN1 | c.15029A>C p.E5010A | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54946474; called by muse, mutect2, varscan2
- HOXD3 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99980177; called by muse, mutect2, varscan2
- HTR1A | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60503265; called by muse, mutect2, varscan2
- HTR2A | c.698A>C p.N233T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV66328595; called by muse, mutect2, varscan2
- IGF2 | c.359G>A p.R120H (on ENST00000434045 / NM_001127598.3; = p.R64H on NM_000612.6) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs369844466; called by muse, mutect2, varscan2
- IL13RA2 | c.1125A>C p.E375D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54567861; called by muse, mutect2
- IMMP2L | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59275930; called by muse, mutect2, varscan2
- ITIH6 | c.2728A>G p.S910G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54489273, COSV54495560; called by muse, mutect2
- ITIH6 | c.2571A>C p.K857N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54495574; called by muse, mutect2, varscan2
- JAM3 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1307104189, COSV54452091; called by muse, mutect2, varscan2
- KCNH1 | c.1064T>G p.V355G (on ENST00000271751 / NM_172362.3; = p.V328G on NM_002238.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55107492; called by muse, mutect2, varscan2
- KCNMB2 | c.453T>G p.N151K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV64201510; called by muse, mutect2, varscan2
- KIAA0408 | c.1517A>G p.E506G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV100846931; called by muse, mutect2, varscan2
- KIF2B | c.1779A>T p.K593N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV52128672, COSV52136221; called by muse, mutect2, varscan2
- KLHL6 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs776911567, COSV58070359; called by muse, mutect2, varscan2
- LBHD1 | c.795_797del p.P266del (on ENST00000431002 / NM_001367940.1; = p.P240del on NM_024099.3) | In Frame Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs779052247; called by pindel, varscan2
- LCP1 | c.335T>G p.V112G | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV59943678; called by muse, mutect2, varscan2
- LY9 | c.1776A>C p.E592D | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as COSV54438488; called by muse, mutect2, varscan2
- MAGEA10 | c.42A>C p.E14D | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV54886285; called by muse, mutect2, varscan2
- MAMDC2 | c.1429A>T p.S477C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV65852316, COSV65852685; called by muse, mutect2, varscan2
- MAP2 | c.4303A>G p.R1435G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52310486; called by muse, mutect2
- MAP4K3 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV55719415; called by muse, mutect2, varscan2
- MED13L | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56131716; called by muse, mutect2
- MMP16 | c.734T>G p.V245G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54192299; called by muse, mutect2, varscan2
- MMP16 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54192307; called by muse, mutect2, varscan2
- MOSPD2 | c.265T>G p.L89V | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV66860947; called by muse, mutect2, varscan2
- MPEG1 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV57096169; called by muse, mutect2, varscan2
- MUC16 | c.27365T>G p.L9122R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.133); catalogued as COSV67498808; called by muse, mutect2, varscan2
- MUC16 | c.25616T>G p.L8539R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV67498819; called by muse, mutect2, varscan2
- MUC16 | c.11080A>C p.S3694R | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV67474994; called by muse, mutect2, varscan2
- MUC16 | c.4928T>C p.V1643A | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV67498837; called by muse, mutect2, varscan2
- MXRA5 | c.3211A>C p.N1071H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV54252980; called by muse, mutect2, varscan2
- MYO5B | c.1526T>G p.L509R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53233095; called by muse, mutect2
- NAV2 | c.3568T>G p.S1190A (on ENST00000396087 / NM_001244963.2; = p.S1167A on NM_145117.5) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60666194; called by muse, mutect2, varscan2
- NBEA | c.4861A>G p.S1621G | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.099); catalogued as COSV59768912, COSV59827848; called by muse, mutect2, varscan2
- NEDD4 | c.2128T>G p.L710V (on ENST00000508342 / NM_001284338.1; = p.L291V on NM_006154.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV59062045, COSV59067307; called by muse, mutect2, varscan2
- NEUROD4 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as rs76064726, COSV54474513, COSV99669838; called by muse, mutect2, varscan2
- NKAP | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV65057056; called by muse, mutect2
- NLGN4X | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV52039484; called by muse, mutect2, varscan2
- NLRP1 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV52580083; called by muse, mutect2, varscan2
- NLRP12 | c.2956G>T p.A986S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.524); catalogued as COSV100145312; called by muse, mutect2, varscan2
- NOVA1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57473964; called by muse, mutect2, varscan2
- NRBF2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1179335728, COSV53260766; called by muse, mutect2, varscan2
- NTNG1 | c.1508A>G p.E503G (on ENST00000370068 / NM_001113226.3; = p.E402G on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV64279997; called by muse, mutect2, varscan2
- NYAP2 | c.1294A>G p.S432G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV56017933; called by muse, mutect2
- OR10G9 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV66686947; called by muse, mutect2, varscan2
- OR10T2 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV57781688, COSV57783958; called by muse, mutect2
- OR14K1 | c.529T>G p.C177G | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315223; called by muse, mutect2
- OR2J3 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV65849041, COSV65849641; called by muse, mutect2, varscan2
- OR3A1 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV60163941; called by muse, mutect2, varscan2
- OR4A47 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV71445015; called by muse, mutect2, varscan2
- OR4D5 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58306063, COSV58307098; called by muse, mutect2, varscan2
- OR4K17 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59649253; called by muse, mutect2, varscan2
- OR52A1 | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61093441; called by muse, mutect2, varscan2
- OR52N5 | c.411C>G p.Y137* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | catalogued as COSV57699615; called by muse, mutect2, varscan2
- OR5L2 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65724096; called by muse, varscan2
- OR5L2 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65725375; called by muse, varscan2
- OVCH1 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV58968437; called by muse, mutect2, varscan2
- OXSM | c.903A>C p.E301D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55002841; called by muse, mutect2, varscan2
- P2RY10 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50680303, COSV50687609; called by muse, mutect2, varscan2
- PASD1 | c.2181A>C p.Q727H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV64858173; called by muse, mutect2, varscan2
- PCDH15 | c.5744T>G p.L1915R | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.23); catalogued as COSV57293515; called by muse, mutect2, varscan2
- PCDH19 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1240585527, COSV55272698; called by muse, mutect2, varscan2
- PCDHA5 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65358766; called by muse, mutect2
- PCDHB3 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV50639047; called by muse, mutect2, varscan2
- PCDHGA3 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.258); catalogued as COSV54046780; called by muse, mutect2, varscan2
- PCLO | c.12743A>C p.N4248T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61672693, COSV61676847; called by muse, mutect2
- PEG3 | c.3170A>G p.K1057R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99689062; called by muse, mutect2, varscan2
- PEG3 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV55649772; called by muse, mutect2, varscan2
- PEG3 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55628435; called by muse, mutect2, varscan2
- PELI2 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs772557976, COSV50709950; called by mutect2, varscan2
- PGK1 | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV59371105, COSV59372511; called by muse, mutect2, varscan2
- PHF8 | c.1046T>C p.I349T (on ENST00000357988 / NM_001184896.1; = p.I313T on NM_015107.3) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57688739; called by muse, mutect2, varscan2
- PJA1 | c.1174A>G p.S392G (on ENST00000361478 / NM_145119.4; = p.S204G on NM_022368.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV64053865; called by muse, mutect2, varscan2
- PKHD1L1 | c.3285T>G p.S1095R | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as COSV65755016; called by muse, mutect2, varscan2
- POLR2B | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58903144; called by muse, mutect2, varscan2
- POMC | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV53035850; called by muse, mutect2, varscan2
- POSTN | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV65714937; called by muse, mutect2, varscan2
- POSTN | c.541A>C p.N181H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.247); catalogued as COSV65714939; called by muse, mutect2
- PPEF2 | c.1919A>C p.E640A | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV54426965; called by muse, mutect2, varscan2
- PSMD10 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54264954; called by muse, mutect2, varscan2
- PTPRD | c.4067A>C p.K1356T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1439272694, COSV61931791, COSV61957305; called by muse, mutect2, varscan2
- PUM1 | c.3172A>T p.K1058* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | catalogued as COSV57089194; called by muse, mutect2, varscan2
- RBM33 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56637744; called by muse, mutect2, varscan2
- RBM46 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs1275034229, COSV55982315; called by muse, mutect2, varscan2
- RGS17 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs34438717; called by muse, mutect2, varscan2
- RGS6 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59601697; called by muse, mutect2
- RNF17 | c.1126T>G p.F376V | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55053075, COSV99694135; called by muse, mutect2, varscan2
- ROBO2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59897157; called by muse, mutect2, varscan2
- ROBO4 | c.2488T>A p.Y830N | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60627890, COSV60628470; called by muse, varscan2
- RP1 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435141613, COSV55128407; called by muse, mutect2, varscan2
- RP1 | c.5836T>A p.F1946I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55128435; called by muse, mutect2, varscan2
- RTL4 | c.585A>C p.E195D | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV61207449; called by muse, mutect2, varscan2
- RUBCNL | c.1958T>G p.L653R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV59786236; called by muse, mutect2, varscan2
- SACS | c.9517T>G p.F3173V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV66547605; called by muse, mutect2
- SACS | c.9515A>C p.K3172T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV66544556; called by muse, mutect2
- SEMA5A | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66803191, COSV66806854; called by muse, mutect2, varscan2
- SERPINB10 | c.592T>G p.L198V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV53076066; called by muse, mutect2, varscan2
- SETBP1 | c.2830A>C p.S944R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.483); catalogued as COSV56338718; called by muse, mutect2, varscan2
- SGCZ | c.694T>G p.F232V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV101172137, COSV66016847; called by muse, mutect2
- SI | c.3499T>G p.L1167V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100014645, COSV52303947; called by muse, mutect2
- SLA2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV53413057; called by muse, mutect2, varscan2
- SLC27A4 | c.1500C>A p.Y500* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55962063; called by muse, mutect2, varscan2
- SLC27A6 | c.404T>A p.L135H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52488471; called by muse, mutect2, varscan2
- SLITRK5 | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV61526956; called by muse, mutect2
- SNCAIP | c.2552A>C p.N851T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54422971; called by muse, mutect2, varscan2
- SPEF2 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56795982, COSV56801080; called by muse, mutect2
- SPHKAP | c.673A>G p.S225G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV60896418; called by muse, mutect2, varscan2
- SPINK5 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV56263528; called by muse, mutect2, varscan2
- SPTA1 | c.6712T>G p.L2238V | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63760716; called by muse, mutect2, varscan2
- SPTA1 | c.4641A>C p.E1547D | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV63760720; called by muse, mutect2, varscan2
- SUV39H1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV61921469; called by muse, mutect2, varscan2
- SYT3 | c.484T>G p.L162V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as COSV58895953; called by muse, mutect2, varscan2
- TAF1 | c.908A>T p.Q303L (on ENST00000373790 / NM_138923.4; = p.Q324L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV52127083; called by muse, mutect2, varscan2
- TAS1R3 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1282791674, COSV59566352; called by muse, mutect2, varscan2
- TBC1D32 | c.3466-2A>C p.X1156_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99250370, COSV99251823; called by mutect2, varscan2
- TEFM | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60092806; called by muse, mutect2, varscan2
- TENM1 | c.4443T>G p.C1481W | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64445613; called by muse, mutect2, varscan2
- TENM3 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs749703754, COSV69305365; called by muse, mutect2, varscan2
- TG | c.3368G>A p.G1123D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1437649976, COSV55096733; called by muse, mutect2, varscan2
- THOC2 | c.1949T>A p.F650Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV55556845; called by muse, mutect2, varscan2
- THSD7B | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.361); catalogued as COSV55744130; called by muse, mutect2, varscan2
- THSD7B | c.2787A>C p.Q929H | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV55744149; called by muse, mutect2, varscan2
- TMEM132D | c.2830A>C p.K944Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV67162913; called by muse, mutect2, varscan2
- TMEM198 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60537107; called by muse, mutect2, varscan2
- TPTE2 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as rs778679708, COSV55029459; called by muse, mutect2, varscan2
- TRHR | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100305001, COSV61236862; called by muse, mutect2
- TRIM9 | c.1308T>G p.A436= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV53625796; called by muse, mutect2, varscan2
- TRIML2 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58720198; called by muse, mutect2, varscan2
- TRPA1 | c.2242T>C p.S748P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV51575664; called by muse, mutect2
- TRPS1 | c.464A>C p.K155T (on ENST00000220888 / NM_001330599.2; = p.K168T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV55265127; called by muse, mutect2, varscan2
- TSEN34 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV55477951; called by muse, mutect2, varscan2
- TTLL11 | c.1155G>C p.K385N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58654216; called by muse, mutect2
- TTN | c.86435A>C p.K28812T (on ENST00000591111; = p.K21388T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | PolyPhen possibly damaging (0.9); catalogued as COSV59924476; called by muse, mutect2, varscan2
- TTN | c.48002T>G p.L16001R (on ENST00000591111; = p.L8577R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | PolyPhen possibly damaging (0.858); catalogued as COSV100614439; called by muse, mutect2
- TTN | c.25660A>C p.T8554P (on ENST00000591111; = p.T7627P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | PolyPhen benign (0.062); catalogued as COSV60388781; called by mutect2, varscan2
- TUSC3 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- TUSC3 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV101141925, COSV65887529; called by muse, mutect2, varscan2
- UBR5 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55301990; called by muse, mutect2
- UTP14C | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV73000837; called by muse, mutect2, varscan2
- VCAN | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV54118125; called by muse, varscan2
- XIRP2 | c.5414A>T p.K1805M (on ENST00000628543; = p.K1980M on NM_152381.6) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54738443; called by muse, mutect2
- ZBBX | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as rs745685112, COSV56783960, COSV56803072; called by muse, mutect2
- ZMAT1 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV65660285; called by muse, mutect2, varscan2
- ZNF117 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV51430193; called by muse, mutect2
- ZNF182 | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59359911; called by muse, mutect2, varscan2
- ZNF226 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56198109; called by muse, mutect2, varscan2
- ZNF260 | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV72951301; called by muse, mutect2, varscan2
- ZNF43 | c.256T>G p.F86V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV61684157, COSV61685547; called by muse, mutect2
- ZNF492 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV71761752, COSV71761974; called by muse, mutect2
- ZNF492 | c.232A>C p.N78H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV71762435; called by muse, mutect2, varscan2
- ZNF568 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61742856; called by muse, mutect2, varscan2
- ZNF568 | c.1043A>C p.N348T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as COSV61742634; called by muse, mutect2, varscan2
- ZNF607 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs750129424, COSV62206576, COSV67696619; called by muse, mutect2, varscan2
- ZNF626 | c.291A>C p.K97N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV74131116; called by muse, mutect2, varscan2
- ZNF667 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52640073, COSV99410800; called by muse, mutect2, varscan2
- ZNF718 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV68140721; called by muse, mutect2, varscan2
- CASP8 | c.1292_1293del p.E431Afs*7 (on ENST00000432109 / NM_033355.3; = p.E448Afs*7 on NM_001228.4) | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by pindel, varscan2
- COL1A2 | c.3397_3401dup p.E1134Dfs*8 | Frame Shift Ins (INS) | VAF 9/80 reads (11%) | called by mutect2, pindel
- FAM135B | c.1701del p.E567Dfs*21 | Frame Shift Del (DEL) | VAF 20/177 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.442); called by muse, mutect2
- IGKV1-16 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PSG2 | c.470del p.N157Tfs*9 | Frame Shift Del (DEL) | VAF 45/322 reads (14%) | called by mutect2, varscan2
- XAGE2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2766G>A p.T922= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV65895584; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1935T>G p.T645= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV54472871; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2814A>C p.R938= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV54472881; called by muse, mutect2, varscan2
- ADGRL3 | c.2455T>C p.L819= (on ENST00000506720 / NM_001322402.2; = p.L751= on NM_015236.6) | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as COSV72232114; called by muse, mutect2, varscan2
- ALG13 | c.393T>G p.T131= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52645721; called by muse, mutect2
- APEX2 | c.1119A>G p.Q373= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs1252392426, COSV58188448; ClinVar: likely benign; called by muse, mutect2, varscan2
- C6orf47 | c.243G>A p.E81= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV63264227; called by muse, mutect2
- CASZ1 | c.4245G>A p.R1415= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV65461671; called by muse, mutect2, varscan2
- CD207 | c.630T>C p.S210= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV69652863; called by muse, mutect2, varscan2
- CLDN9 | c.75C>T p.C25= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs368045321, COSV60910462; called by muse, mutect2, varscan2
- CLEC12A | c.18T>G p.T6= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV58561849; called by muse, mutect2
- CPQ | c.376A>C p.R126= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55151781, COSV55161932; called by muse, mutect2
- CRISPLD1 | c.300T>A p.A100= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as COSV51553599; called by muse, mutect2
- CYP11B1 | c.1152A>T p.R384= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV52830771; called by muse, mutect2, varscan2
- ERCC6 | c.2649C>G p.L883= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV63394897; called by muse, mutect2, varscan2
- FAT2 | c.5413T>C p.L1805= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV55828656; called by muse, mutect2, varscan2
- GDI1 | c.117C>T p.Y39= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs782559224, COSV63896367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GH2 | c.540C>T p.D180= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs771150182, COSV60426335; called by muse, mutect2, varscan2
- GPNMB | c.144T>G p.S48= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV51701441; called by muse, mutect2, varscan2
- KIRREL1 | c.1848T>C p.S616= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV63291986; called by muse, mutect2, varscan2
- LCOR | c.2493A>G p.L831= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV53718893; called by muse, mutect2, varscan2
- LRP1B | c.4152T>A p.A1384= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV67280721; called by muse, mutect2
- MAPKBP1 | c.4153T>C p.L1385= (on ENST00000456763 / NM_001128608.2; = p.L1379= on NM_014994.3) | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV52967635; called by muse, mutect2, varscan2
- MYO3B | c.1362T>G p.T454= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV58720091; called by muse, mutect2, varscan2
- NCAN | c.2751G>A p.P917= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as rs764591928, COSV53060225; called by muse, mutect2
- NLGN4X | c.1563C>T p.A521= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs144614029, COSV52039432; called by muse, mutect2, varscan2
- NLGN4X | c.360G>A p.L120= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV52039461; called by muse, mutect2, varscan2
- NUP93 | c.321C>T p.D107= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs372055823; called by muse, mutect2, varscan2
- PABPC5 | c.627C>T p.D209= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV57043539; called by muse, mutect2, varscan2
- PCLO | c.11569A>C p.R3857= | Silent (SNP) | VAF 56/303 reads (18%) | catalogued as COSV61616419, COSV61672717; called by muse, mutect2, varscan2
- PDE4B | c.870T>C p.S290= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV58498410; called by muse, mutect2, varscan2
- PRAMEF20 | c.1066T>C p.L356= | Silent (SNP) | VAF 87/544 reads (16%) | called by muse, mutect2, varscan2
- RBM19 | c.798G>A p.G266= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV55699637; called by muse, mutect2, varscan2
- RERG | c.364T>C p.L122= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as COSV57005769; called by muse, mutect2, varscan2
- S100A7A | c.12T>A p.T4= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV61331483; called by muse, mutect2, varscan2
- SETBP1 | c.2235C>T p.A745= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99953397; called by muse, mutect2, varscan2
- SIN3B | c.303C>T p.N101= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs920953077, COSV56136258; called by muse, mutect2, varscan2
- SLC6A16 | c.150A>G p.Q50= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV60030970; called by muse, mutect2, varscan2
- SLC8A1 | c.1162A>C p.R388= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV60498233; called by muse, mutect2, varscan2
- SLITRK2 | c.2286A>G p.R762= | Silent (SNP) | VAF 38/254 reads (15%) | catalogued as COSV59429451; called by muse, varscan2
- ST3GAL1 | c.546G>A p.G182= | Silent (SNP) | VAF 35/243 reads (14%) | catalogued as COSV60617236; called by muse, mutect2, varscan2
- SVEP1 | c.1044C>T p.H348= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57049548; called by muse, mutect2, varscan2
- SYCP2L | c.564T>C p.T188= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV51658222; called by muse, mutect2, varscan2
- TM6SF1 | c.405T>G p.T135= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV51946814; called by muse, mutect2
- TMPRSS15 | c.2016A>C p.S672= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV53050480; called by muse, mutect2, varscan2
- TRAV1-1 | c.234T>G p.S78= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- TRO | c.1428A>G p.Q476= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV51508772; called by muse, mutect2
- VCAN | c.1323T>G p.P441= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV54118133; called by muse, varscan2
- VCAN | c.7270T>C p.L2424= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV54118143; called by muse, mutect2, varscan2
- VCAN | c.7968T>G p.T2656= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV54100003, COSV54118155; called by muse, mutect2, varscan2
- VPS54 | c.2187T>C p.A729= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55445990; called by muse, mutect2, varscan2
- ZFYVE26 | c.5268C>T p.P1756= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs757534059, COSV61327779; called by muse, mutect2, varscan2
- ZNF426 | c.1150A>C p.R384= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV53470923; called by muse, mutect2, varscan2
- ZNF549 | c.621A>G p.Q207= (on ENST00000376233 / NM_001199295.2; = p.Q194= on NM_153263.2) | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV53727090, COSV53728067; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83172T>C | Intron (SNP) | VAF 99/374 reads (26%) | called by muse, mutect2, varscan2
- COL11A1 | c.898-259del | Intron (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.*2925A>C | 3'UTR (SNP) | VAF 5/26 reads (19%) | catalogued as COSV57076147; called by muse, mutect2, varscan2
- GLRXP3 | n.174A>G | RNA (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- HSD3B2 | c.-2C>T | 5'UTR (SNP) | VAF 11/77 reads (14%) | catalogued as rs187042846; called by muse, mutect2, varscan2
- LIM2 | c.175+28G>A | Intron (SNP) | VAF 17/110 reads (15%) | catalogued as rs199913969, COSV55741027, COSV99702300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR3 | c.*3344T>G | 3'UTR (SNP) | VAF 11/95 reads (12%) | catalogued as rs748479373, COSV54093889; called by muse, varscan2
- OR2U1P | n.182T>G | RNA (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- SNORD116-8 | n.64T>C | RNA (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10360+3957A>G | Intron (SNP) | VAF 7/58 reads (12%) | catalogued as COSV60388792; called by muse, mutect2, varscan2
- TTN | c.10360+1798A>C | Intron (SNP) | VAF 14/76 reads (18%) | catalogued as COSV60139727; called by muse, mutect2, varscan2
